Somatic mutation profile of tumor specimen MBCProject_3896_T5_WES (aliquot MBCProject_3896_T5_WES_1) from CMI case MBCProject_3896, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 70.2 years (25,655 days).
Specimen MBCProject_3896_T5_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Pleura; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 041bda71-838c-40fb-b1c7-7b48ba5c63fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3896_SALIVA (Saliva), aliquot MBCProject_3896_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2751177e-900d-498f-83f8-bc0a25f5db81

The open-access MAF lists 226 somatic variants for this specimen: 138 protein-altering or splice-affecting, 52 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 52, Intron 16, Nonsense Mutation 12, 5'UTR 9, RNA 4, 3'UTR 3, 3'Flank 3, Splice Site 2, Frame Shift Del 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESR1 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 67/688 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1057519827, COSV52782264; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ESR1 | c.1609T>A p.Y537N | Missense Mutation (SNP) | VAF 115/935 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52784978, COSV52804811, COSV99237981; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 38/135 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM7 | c.1931G>T p.G644V | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs1334029936; called by muse, mutect2
- ADAMTSL3 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 44/422 reads (10%) | catalogued as COSV54446085, COSV99716519; called by muse, mutect2
- ADH1A | c.887C>G p.P296R | Missense Mutation (SNP) | VAF 36/398 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52924648; called by muse, mutect2
- AHCTF1 | c.6055G>A p.E2019K (on ENST00000366508; = p.E1993K on NM_015446.5) | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.085); catalogued as COSV58255473; called by muse, mutect2, varscan2
- ANKRD45 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100322686; called by muse, mutect2
- ANKRD66 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.124); catalogued as COSV71666091; called by muse, mutect2
- ASXL3 | c.5059C>T p.P1687S | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); catalogued as rs1168031356, COSV99325969; called by muse, mutect2
- BMP4 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs1237655395; called by muse, mutect2
- CLEC9A | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs997271993; called by muse, mutect2, varscan2
- CNOT6 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56163640; called by muse, mutect2, varscan2
- CYTL1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 52/642 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.36); catalogued as rs137887145, COSV57037313; called by muse, mutect2
- FLG2 | c.5234C>T p.S1745L | Missense Mutation (SNP) | VAF 36/530 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs1228290098; called by muse, mutect2
- GLT6D1 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs756561670, COSV65627142; called by muse, mutect2
- HAO1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 43/512 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.201); catalogued as rs200686504, COSV66493396; called by muse, mutect2
- HEY1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 44/892 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV61232637; called by muse, mutect2
- HSPA13 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 48/459 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV53465501; called by muse, mutect2, varscan2
- IGHV1-18 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 54/670 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.361); catalogued as rs561015233; called by muse, mutect2
- KNDC1 | c.2683G>C p.E895Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV58839456; called by muse, mutect2
- MKI67 | c.1729G>T p.V577F | Missense Mutation (SNP) | VAF 46/496 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV64077502; called by muse, mutect2
- MUC5B | c.13419G>T p.Q4473H | Missense Mutation (SNP) | VAF 53/688 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV101500297; called by muse, mutect2
- MYO1D | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 16/263 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59024000; called by muse, mutect2
- N4BP2L2 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 29/465 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57227461; called by muse, mutect2
- NES | c.2661G>C p.E887D | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV104427526; called by muse, mutect2
- NR1I2 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 77/848 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs201179068, COSV61978948; called by muse, mutect2
- OR1M1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 39/327 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs1332959232, COSV101447568, COSV101447600; called by muse, mutect2, varscan2
- OR4C6 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV100051526, COSV100051727; called by muse, mutect2
- PCDH10 | c.441C>G p.F147L | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.13); catalogued as rs757923593, COSV52091331; called by muse, mutect2
- PPIP5K2 | c.3649C>T p.P1217S (on ENST00000358359 / NM_001276277.3; = p.P1196S on NM_015216.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs782146288; called by muse, varscan2
- PREX2 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 46/860 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55749568; called by muse, mutect2
- PRPH | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.059); catalogued as COSV99142076; called by muse, mutect2, varscan2
- PTAFR | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59536724; called by muse, mutect2, varscan2
- RAD50 | c.1982G>C p.G661A | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); catalogued as rs758063640; ClinVar: uncertain significance; called by muse, mutect2
- RARA | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV54191223; called by muse, mutect2
- RPTOR | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs770209703; called by muse, mutect2
- SIPA1L3 | c.2613C>G p.I871M | Missense Mutation (SNP) | VAF 29/611 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV55909455; called by muse, mutect2
- SLC45A1 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 26/331 reads (8%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.968); catalogued as rs763910011; called by muse, mutect2
- SLFN12 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV59227284; called by muse, mutect2, varscan2
- SRPK2 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 52/620 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1340874246, COSV100624330, COSV61963906; called by muse, mutect2
- TBC1D2 | c.1309C>G p.P437A | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as rs375721269; called by muse, mutect2, varscan2
- TP53BP1 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 24/267 reads (9%) | catalogued as COSV99781802; called by muse, mutect2
- TRIM10 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 60/985 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs769419657, COSV100938926, COSV64989187; called by muse, mutect2
- TTN | c.76948G>A p.E25650K (on ENST00000591111; = p.E18226K on NM_003319.4) | Missense Mutation (SNP) | VAF 59/526 reads (11%) | PolyPhen benign (0.254); catalogued as COSV60187286; called by muse, mutect2, varscan2
- UNKL | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 53/566 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.06); catalogued as rs574913319, COSV50190477, COSV99201402; called by muse, mutect2
- ZNF451 | c.1195T>A p.L399I | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV62597107, COSV62598161; called by muse, mutect2
- ZNF830 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs1567676596; called by muse, mutect2
- ABCF1 | c.1393G>A p.A465T (on ENST00000326195 / NM_001025091.2; = p.A427T on NM_001090.3) | Missense Mutation (SNP) | VAF 48/444 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM11 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 25/310 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.102); called by muse, mutect2
- ADAM32 | c.354-1G>C p.X118_splice | Splice Site (SNP) | VAF 22/127 reads (17%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.2289C>G p.F763L | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.192); called by muse, mutect2
- ALDH9A1 | c.1370G>C p.R457T | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- ARHGEF10 | c.2349_2350del p.V784Sfs*3 (on ENST00000398564; = p.V759Sfs*3 on NM_014629.4) | Frame Shift Del (DEL) | VAF 62/431 reads (14%) | called by mutect2, pindel, varscan2
- ARL6 | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMC2 | c.2262G>C p.L754F | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATN1 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); called by muse, mutect2
- BAALC | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 46/696 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- BATF | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 26/391 reads (7%) | called by muse, mutect2
- BUB1B | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMKMT | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CMYA5 | c.8154G>C p.E2718D | Missense Mutation (SNP) | VAF 10/267 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- COPB2 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CRYBG2 | c.3949C>T p.Q1317* | Nonsense Mutation (SNP) | VAF 47/486 reads (10%) | called by muse, mutect2
- CTAGE1 | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DIO3 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- DRD1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 31/311 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DSCC1 | c.585G>A p.W195* | Nonsense Mutation (SNP) | VAF 13/332 reads (4%) | called by muse, mutect2
- EGFLAM | c.177G>C p.R59S | Missense Mutation (SNP) | VAF 23/255 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, mutect2
- EGFLAM | c.2181G>C p.Q727H | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- EIF2AK2 | c.1540C>A p.L514I | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EPM2A | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2
- FAM111B | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- GCNT4 | c.190A>T p.K64* | Nonsense Mutation (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- GDPD2 | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 38/375 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GSTA4 | c.403G>T p.V135L | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2
- HAUS5 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 32/673 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2
- HCAR3 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 42/714 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2
- HDAC3 | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 44/540 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- HK3 | c.2470A>T p.M824L | Missense Mutation (SNP) | VAF 26/319 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- HLA-DQA2 | c.621G>C p.E207D | Missense Mutation (SNP) | VAF 62/957 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2
- HOMER1 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HRH3 | c.1326C>A p.H442Q | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2
- IL19 | c.361T>C p.C121R | Missense Mutation (SNP) | VAF 58/618 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IQCB1 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.376); called by muse, mutect2
- IWS1 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 42/614 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2
- JAG2 | c.476-1G>C p.X159_splice | Splice Site (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- JAKMIP2 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 25/358 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2
- KLK4 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 37/784 reads (5%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.99); called by muse, mutect2
- LRP1 | c.2665C>G p.L889V | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LSAMP | c.616G>C p.A206P | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- MAP1B | c.5504C>T p.S1835L | Missense Mutation (SNP) | VAF 36/596 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2
- MAP7D2 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MUC16 | c.22127G>T p.G7376V | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- MYH6 | c.4156G>T p.E1386* | Nonsense Mutation (SNP) | VAF 52/632 reads (8%) | called by muse, mutect2
- MYL6B | c.588C>G p.I196M | Missense Mutation (SNP) | VAF 28/425 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- MYO18B | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- NARS2 | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NFXL1 | c.1268A>C p.E423A | Missense Mutation (SNP) | VAF 32/329 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- NUP107 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- NWD1 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 46/434 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- OR4S1 | c.659T>A p.L220* | Nonsense Mutation (SNP) | VAF 28/440 reads (6%) | called by muse, mutect2
- PALM | c.675C>A p.H225Q | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PCDHA11 | c.107C>G p.S36W | Missense Mutation (SNP) | VAF 46/716 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); called by muse, mutect2
- PDCD5 | c.36G>C p.Q12H | Missense Mutation (SNP) | VAF 19/424 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- PIEZO2 | c.8C>A p.S3* | Nonsense Mutation (SNP) | VAF 30/350 reads (9%) | called by muse, mutect2
- PRKDC | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.049); called by muse, mutect2
- PSKH1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSKH1 | c.685C>G p.P229A | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- QSOX1 | c.1657A>T p.R553W | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- RAB3GAP2 | c.3905C>G p.S1302C | Missense Mutation (SNP) | VAF 52/581 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAD50 | c.1818G>C p.Q606H | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.283); called by muse, mutect2
- RAD50 | c.2205G>A p.M735I | Missense Mutation (SNP) | VAF 42/772 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- RBM19 | c.995A>C p.K332T | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.076); called by muse, mutect2
- RXFP1 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- SCN3A | c.3184A>C p.N1062H | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- SIRT4 | c.413A>T p.Y138F | Missense Mutation (SNP) | VAF 94/613 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SLC22A17 | n.1281A>T | Splice Region (SNP) | VAF 35/302 reads (12%) | called by muse, mutect2, varscan2
- SMARCA2 | c.4570G>A p.D1524N | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- SPINT2 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 68/1202 reads (6%) | called by muse, mutect2
- STAB2 | c.5198C>A p.P1733H | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TAMALIN | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TENM2 | c.2845G>C p.V949L (on ENST00000518659 / NM_001122679.2; = p.V717L on NM_001080428.3) | Missense Mutation (SNP) | VAF 73/587 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEX30 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM68 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- TNRC6A | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 33/393 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2
- TOGARAM1 | c.5060C>A p.A1687E | Missense Mutation (SNP) | VAF 37/495 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.284); called by muse, mutect2
- VDAC1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- VIPAS39 | c.143A>T p.D48V | Missense Mutation (SNP) | VAF 117/1308 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2
- WDR87 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 34/705 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WRNIP1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- ZFYVE26 | c.2997G>C p.L999F | Missense Mutation (SNP) | VAF 52/780 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF229 | c.1410C>G p.F470L | Missense Mutation (SNP) | VAF 32/1000 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- ZNF320 | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2
- ZNF486 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ZNF546 | c.2416C>T p.Q806* | Nonsense Mutation (SNP) | VAF 9/208 reads (4%) | called by muse, mutect2
- ZNF551 | c.409A>T p.S137C | Missense Mutation (SNP) | VAF 34/578 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF574 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACVR2B | c.180C>T p.Y60= | Silent (SNP) | VAF 102/865 reads (12%) | catalogued as rs776365961; called by muse, mutect2, varscan2
- ADCK5 | c.507G>A p.V169= | Silent (SNP) | VAF 32/572 reads (6%) | called by muse, mutect2
- APBA1 | c.1812C>T p.I604= | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as rs371740590; called by muse, mutect2
- ARFIP2 | c.999G>A p.E333= | Silent (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- ARFRP1 | c.492G>T p.L164= | Silent (SNP) | VAF 39/440 reads (9%) | called by muse, mutect2
- ATAD2 | c.117C>G p.L39= | Silent (SNP) | VAF 27/565 reads (5%) | catalogued as COSV54877507; called by muse, mutect2
- C1orf109 | c.219G>C p.L73= | Silent (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
- CAMK1D | c.777G>C p.L259= | Silent (SNP) | VAF 15/244 reads (6%) | called by muse, mutect2
- CBL | c.729C>A p.I243= | Silent (SNP) | VAF 38/544 reads (7%) | called by muse, mutect2
- CBX8 | c.600C>T p.G200= | Silent (SNP) | VAF 45/365 reads (12%) | catalogued as rs757296700; called by muse, mutect2, varscan2
- DMRTA1 | c.927C>G p.V309= | Silent (SNP) | VAF 51/395 reads (13%) | called by muse, mutect2, varscan2
- DNAH8 | c.11109C>T p.I3703= | Silent (SNP) | VAF 28/358 reads (8%) | catalogued as COSV100547447; called by muse, mutect2
- DOCK5 | c.4461C>T p.T1487= | Silent (SNP) | VAF 20/392 reads (5%) | called by muse, mutect2
- DPH2 | c.1419G>A p.V473= | Silent (SNP) | VAF 24/364 reads (7%) | called by muse, mutect2
- DUOXA2 | c.483C>T p.F161= | Silent (SNP) | VAF 37/363 reads (10%) | called by muse, mutect2, varscan2
- EPN2 | c.330G>A p.Q110= | Silent (SNP) | VAF 35/284 reads (12%) | catalogued as COSV59063343; called by muse, mutect2, varscan2
- FAM171A1 | c.1599C>T p.D533= | Silent (SNP) | VAF 31/346 reads (9%) | called by muse, mutect2
- FCN1 | c.9G>C p.L3= | Silent (SNP) | VAF 17/268 reads (6%) | catalogued as COSV65662511; called by muse, mutect2
- FOSB | c.621G>A p.E207= | Silent (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2
- GRIA1 | c.147C>T p.L49= | Silent (SNP) | VAF 32/518 reads (6%) | called by muse, mutect2
- GRIK3 | c.1254G>A p.E418= | Silent (SNP) | VAF 42/404 reads (10%) | called by muse, mutect2, varscan2
- HBA2 | c.345C>T p.P115= | Silent (SNP) | VAF 75/839 reads (9%) | catalogued as CD066366, COSV52406697; called by muse, mutect2, varscan2
- HSPA8 | c.591C>T p.I197= | Silent (SNP) | VAF 23/227 reads (10%) | catalogued as COSV57083664; called by muse, mutect2, varscan2
- KCNA1 | c.144C>T p.F48= | Silent (SNP) | VAF 39/610 reads (6%) | catalogued as rs886042316, COSV66836780; ClinVar: uncertain significance; called by muse, mutect2
- KCNH4 | c.1458G>T p.S486= | Silent (SNP) | VAF 47/429 reads (11%) | called by muse, mutect2, varscan2
- KRT37 | c.411C>T p.L137= | Silent (SNP) | VAF 49/488 reads (10%) | catalogued as rs762388047, COSV56656819; called by muse, mutect2, varscan2
- MADD | c.2583C>T p.F861= | Silent (SNP) | VAF 36/433 reads (8%) | catalogued as COSV100212176; called by muse, mutect2
- MARCHF6 | c.2241G>C p.L747= | Silent (SNP) | VAF 71/759 reads (9%) | catalogued as COSV99930080; called by muse, mutect2
- MED13 | c.3102C>T p.V1034= | Silent (SNP) | VAF 28/312 reads (9%) | called by muse, mutect2
- MRPL14 | c.18G>T p.G6= | Silent (SNP) | VAF 39/394 reads (10%) | called by muse, mutect2
- MYLK | c.2217C>A p.L739= | Silent (SNP) | VAF 55/530 reads (10%) | called by muse, mutect2, varscan2
- P2RX2 | c.687C>T p.H229= (on ENST00000343948 / NM_170683.4; = p.H157= on NM_012226.5) | Silent (SNP) | VAF 36/429 reads (8%) | catalogued as rs754679844; called by muse, mutect2
- PAX1 | c.96G>A p.A32= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs1302813262; called by muse, mutect2
- PSMB6 | c.384G>A p.L128= | Silent (SNP) | VAF 26/330 reads (8%) | called by muse, mutect2
- PSME2 | c.333C>T p.V111= | Silent (SNP) | VAF 26/302 reads (9%) | called by muse, mutect2
- PTCH2 | c.378C>T p.I126= | Silent (SNP) | VAF 43/436 reads (10%) | catalogued as rs1169569324; called by muse, varscan2
- RAB19 | c.36G>A p.E12= | Silent (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2
- RRS1 | c.654G>A p.L218= | Silent (SNP) | VAF 171/341 reads (50%) | called by muse, mutect2, varscan2
- SKIDA1 | c.138C>T p.H46= | Silent (SNP) | VAF 24/358 reads (7%) | called by muse, mutect2
- SLC6A16 | c.306C>A p.A102= | Silent (SNP) | VAF 54/446 reads (12%) | called by muse, mutect2, varscan2
- SYNE4 | c.606C>G p.V202= | Silent (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- TBX4 | c.267C>T p.I89= | Silent (SNP) | VAF 30/306 reads (10%) | called by muse, mutect2
- THBD | c.615G>A p.Q205= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.2769A>G p.E923= | Silent (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- TRIM23 | c.999A>G p.S333= | Silent (SNP) | VAF 40/548 reads (7%) | called by muse, mutect2
- TRIM65 | c.69G>A p.V23= | Silent (SNP) | VAF 30/416 reads (7%) | called by muse, mutect2
- TRMT61B | c.216G>C p.L72= | Silent (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- TSGA13 | c.720C>G p.L240= | Silent (SNP) | VAF 51/559 reads (9%) | called by muse, mutect2
- UTP20 | c.2604G>C p.R868= | Silent (SNP) | VAF 38/530 reads (7%) | called by muse, mutect2
- UTP25 | c.2253C>T p.F751= | Silent (SNP) | VAF 15/220 reads (7%) | called by muse, mutect2
- WDR97 | c.225C>T p.T75= | Silent (SNP) | VAF 21/268 reads (8%) | catalogued as rs1231178876; called by muse, mutect2
- ZFHX4 | c.624T>C p.D208= | Silent (SNP) | VAF 84/971 reads (9%) | called by muse, mutect2
- AC018638.4 | n.358C>T | RNA (SNP) | VAF 291/1125 reads (26%) | called by muse, mutect2, varscan2
- ASPM | c.*50A>G | 3'UTR (SNP) | VAF 14/154 reads (9%) | catalogued as rs554369669; called by muse, mutect2
- C19orf84 | c.35+23G>A | Intron (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- CASP2 | c.-17C>G | 5'UTR (SNP) | VAF 24/195 reads (12%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93735132 C>G | 3'Flank (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2
- CIRBP | chr19:1268280 G>T | 5'Flank (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
- COL20A1 | c.3295-201C>G | Intron (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- COLEC11 | c.328+926A>T | Intron (SNP) | VAF 57/545 reads (10%) | called by muse, mutect2, varscan2
- DDX39B | c.-452C>T | 5'UTR (SNP) | VAF 21/292 reads (7%) | called by muse, mutect2
- DHX30 | c.125-2211C>A | Intron (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2
- DIABLO | c.-1G>T | 5'UTR (SNP) | VAF 32/368 reads (9%) | called by muse, mutect2
- DST | c.20247+69T>A | Intron (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2, varscan2
- ETS2 | c.-256C>T | 5'UTR (SNP) | VAF 28/324 reads (9%) | catalogued as COSV100711339; called by muse, mutect2
- FAM181A | c.-35C>A | 5'UTR (SNP) | VAF 119/439 reads (27%) | called by muse, mutect2, varscan2
- GABBR1 | c.*273C>A | 3'UTR (SNP) | VAF 34/462 reads (7%) | called by muse, mutect2
- GABPB1 | c.-1+568C>G | Intron (SNP) | VAF 24/288 reads (8%) | called by muse, mutect2
- HNRNPU | c.634+1129C>T | Intron (SNP) | VAF 28/308 reads (9%) | catalogued as rs779983935, COSV51692635; called by muse, mutect2
- HSPA7 | n.765G>A | RNA (SNP) | VAF 45/591 reads (8%) | called by muse, mutect2
- KCNAB1 | c.276-129664G>A | Intron (SNP) | VAF 64/819 reads (8%) | called by muse, mutect2
- MASP1 | c.1091-47G>T | Intron (SNP) | VAF 44/493 reads (9%) | called by muse, mutect2
- MKI67 | c.-18C>G | 5'UTR (SNP) | VAF 53/565 reads (9%) | called by muse, mutect2
- MMADHC | c.9+16C>T | Intron (SNP) | VAF 32/452 reads (7%) | catalogued as rs774042094; called by muse, mutect2
- MPV17 | c.71-33G>C | Intron (SNP) | VAF 30/396 reads (8%) | catalogued as rs1445492059; called by muse, mutect2
- MYO15B | c.8054-10G>A | Intron (SNP) | VAF 18/222 reads (8%) | catalogued as rs112815361; called by muse, mutect2
- NBPF22P | n.583G>T | RNA (SNP) | VAF 22/422 reads (5%) | called by muse, mutect2
- ORC3 | c.-26C>G | 5'UTR (SNP) | VAF 37/262 reads (14%) | called by muse, mutect2, varscan2
- PAQR5 | c.513-48G>A | Intron (SNP) | VAF 20/215 reads (9%) | catalogued as rs1264253481; called by muse, mutect2
- PHF2 | c.*1606G>C | 3'UTR (SNP) | VAF 51/454 reads (11%) | called by muse, mutect2, varscan2
- PRND | chr20:4732519 G>T | 3'Flank (SNP) | VAF 72/850 reads (8%) | called by muse, mutect2
- RAD51C | c.-1G>T | 5'UTR (SNP) | VAF 34/676 reads (5%) | catalogued as rs750045091; called by muse, mutect2
- SPATA31C1 | n.3472G>C | RNA (SNP) | VAF 76/749 reads (10%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-3C>T | 5'UTR (SNP) | VAF 16/166 reads (10%) | catalogued as rs776687705, COSV56552223; called by muse, mutect2
- TRPV2 | chr17:16441303 C>T | 3'Flank (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- UNKL | c.1585+113T>A | Intron (SNP) | VAF 16/220 reads (7%) | called by muse, mutect2
- YPEL2 | c.117+127C>T | Intron (SNP) | VAF 22/256 reads (9%) | catalogued as rs754283120; called by muse, mutect2
- ZNF662 | c.-94+175A>C | Intron (SNP) | VAF 35/183 reads (19%) | called by muse, mutect2, varscan2
